Somatic mutation profile of tumor specimen C3L-07979-02 (aliquot CPT0480870006) from CPTAC case C3L-07979, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,611 days).
Specimen C3L-07979-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af44be75-9ff8-426f-829e-e4b5968ea2f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07979-31 (Blood Derived Normal), aliquot CPT0481010003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0eca515-84d1-4779-a6e6-4f5316479d72

The open-access MAF lists 313 somatic variants for this specimen: 231 protein-altering or splice-affecting, 68 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 200, Silent 68, Nonsense Mutation 20, Intron 6, Splice Region 3, 5'UTR 3, Splice Site 2, 5'Flank 2, RNA 2, In Frame Del 2, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 56/223 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 168/254 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.3679G>A p.E1227K | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.259); catalogued as COSV53239851; called by muse, mutect2
- ADGRF3 | c.1184G>A p.R395H (on ENST00000311519 / NM_001145168.1; = p.R196H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/375 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs142282428; called by muse, mutect2, varscan2
- ADGRL3 | c.4699G>A p.E1567K (on ENST00000506720 / NM_001322402.2; = p.E1456K on NM_015236.6) | Missense Mutation (SNP) | VAF 72/329 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1020254329; called by muse, mutect2, varscan2
- ADNP | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 126/763 reads (17%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.992); catalogued as rs769680032; called by muse, mutect2, varscan2
- ANGPT1 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 65/483 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99864966; called by muse, mutect2, varscan2
- ANO6 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.222); catalogued as rs772758085; called by muse, mutect2, varscan2
- ARF1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.311); catalogued as COSV55254137; called by muse, mutect2, varscan2
- ASTN1 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as rs572008459, COSV99922651, COSV99923514; called by muse, mutect2, varscan2
- BIRC6 | c.2722C>G p.Q908E | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs907369598, COSV70203962; called by muse, mutect2, varscan2
- BROX | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 135/220 reads (61%) | catalogued as COSV61798912; called by muse, mutect2, varscan2
- C1QTNF5 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 177/644 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.843); catalogued as rs1316657035; called by muse, mutect2, varscan2
- CCL3L3 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 222/474 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1166624794; called by muse, varscan2
- CFAP52 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 200/349 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as rs1056801078; called by muse, mutect2, varscan2
- CHM | c.1748G>A p.G583E | Missense Mutation (SNP) | VAF 73/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs936248789; called by muse, mutect2, varscan2
- CHST14 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 81/516 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV60379223; called by muse, mutect2, varscan2
- CNTNAP2 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 114/437 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV62244764; called by muse, mutect2, varscan2
- CSMD3 | c.1213G>T p.G405C | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.286); catalogued as COSV52307630; called by muse, mutect2, varscan2
- CSRP1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV60637117; called by muse, mutect2, varscan2
- CTSO | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.627); catalogued as rs138871272; called by muse, mutect2, varscan2
- CUL7 | c.3349C>T p.R1117W | Missense Mutation (SNP) | VAF 72/459 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as rs375832364; called by muse, mutect2, varscan2
- DCC | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV59143860; called by muse, mutect2, varscan2
- DDX21 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs781361962; called by muse, mutect2, varscan2
- DMXL2 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 204/524 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99196094; called by muse, mutect2, varscan2
- DOCK8 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 101/223 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as rs769150252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYTN | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 94/299 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1355381574; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1953C>G p.F651L (on ENST00000361735 / NM_015935.5; = p.F565L on NM_014955.3) | Missense Mutation (SNP) | VAF 139/606 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs1403100024; called by muse, mutect2, varscan2
- FERD3L | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs748759205; called by muse, mutect2, varscan2
- FMN1 | c.3661G>T p.G1221W (on ENST00000616417 / NM_001277313.2; = p.G998W on NM_001103184.4) | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57934765; called by muse, mutect2
- FSHR | c.153G>A p.L51= | Splice Region (SNP) | VAF 26/240 reads (11%) | catalogued as COSV58620432, COSV58625002; called by muse, mutect2, varscan2
- FZD8 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 59/491 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.148); catalogued as rs753375253; called by muse, mutect2, varscan2
- GBP2 | c.1681G>C p.E561Q | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.432); catalogued as rs777905188; called by muse, mutect2, varscan2
- GGA2 | c.1_15del p.MAATA1_?5 | Translation Start Site (DEL) | VAF 58/257 reads (23%) | catalogued as rs1015231347; called by mutect2, pindel, varscan2
- GSPT1 | c.197C>T p.P66L (on ENST00000420576 / NM_001130007.2; = p.P204L on NM_002094.4) | Missense Mutation (SNP) | VAF 113/344 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs961685675; called by muse, mutect2, varscan2
- GSTCD | c.731C>G p.S244* (on ENST00000360505 / NM_001031720.3; = p.S157* on NM_024751.3) | Nonsense Mutation (SNP) | VAF 48/262 reads (18%) | catalogued as COSV100853794, COSV100853867; called by muse, mutect2, varscan2
- GTF3C1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs757783362; called by muse, varscan2
- HERC1 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71250306; called by muse, mutect2
- HOMER2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 96/424 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs779506706, COSV58487502; called by muse, mutect2, varscan2
- HRC | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53257519; called by muse, mutect2, varscan2
- IGHV2-5 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs781980957; called by muse, mutect2, varscan2
- KDR | c.1455G>C p.W485C | Missense Mutation (SNP) | VAF 40/349 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55769386; called by muse, mutect2, varscan2
- KLRF1 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 50/280 reads (18%) | catalogued as COSV99684329; called by muse, mutect2, varscan2
- LONP1 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs763812313; called by muse, mutect2, varscan2
- LZTS3 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 60/865 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.206); catalogued as COSV61278137; called by muse, mutect2
- MACROD2 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs1296831843, COSV53979675; called by muse, mutect2, varscan2
- MAMDC2 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 54/439 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs373309195; called by muse, mutect2, varscan2
- MAP2 | c.3283G>C p.E1095Q | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV52300100; called by muse, mutect2, varscan2
- MATN4 | c.1520C>G p.S507W (on ENST00000372754; = p.S466W on NM_003833.4) | Missense Mutation (SNP) | VAF 63/743 reads (8%) | PolyPhen probably damaging (0.997); catalogued as COSV61352054; called by muse, mutect2
- MED13 | c.5205G>C p.L1735F | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327125058; called by muse, mutect2, varscan2
- MEGF10 | c.966G>T p.E322D | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.232); catalogued as COSV57249478, COSV57256676; called by muse, mutect2, varscan2
- MGA | c.7906G>T p.A2636S (on ENST00000219905 / NM_001164273.1; = p.A2427S on NM_001080541.2) | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs1358115067; called by muse, mutect2, varscan2
- MINDY4 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 84/437 reads (19%) | catalogued as rs770851252, COSV99518726; called by muse, mutect2, varscan2
- MTLN | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV101345857; called by muse, mutect2, varscan2
- MUC16 | c.20690G>C p.G6897A | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.07); catalogued as COSV67494323; called by muse, mutect2, varscan2
- MUTYH | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 46/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779997419, COSV58343701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.4334C>T p.P1445L | Missense Mutation (SNP) | VAF 94/804 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs763308655; called by muse, mutect2, varscan2
- MYO3A | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56349062; called by muse, mutect2, varscan2
- NEO1 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1185658983, COSV56068746; called by muse, mutect2, varscan2
- NFRKB | c.1931G>A p.R644Q (on ENST00000446488 / NM_001143835.2; = p.R669Q on NM_006165.3) | Missense Mutation (SNP) | VAF 78/395 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1336797284; called by muse, mutect2, varscan2
- OBSCN | c.23215C>T p.R7739W | Missense Mutation (SNP) | VAF 77/585 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs766510653; called by muse, mutect2, varscan2
- OR13G1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 117/734 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62943780; called by muse, mutect2, varscan2
- OR2G2 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 50/720 reads (7%) | catalogued as COSV60739212; called by muse, mutect2
- OR4C15 | c.743T>G p.F248C (on ENST00000314644; = p.F194C on NM_001001920.2) | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100116194; called by muse, mutect2, varscan2
- OR4K14 | c.807C>A p.D269E | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV59292733; called by muse, mutect2, varscan2
- OXR1 | c.865G>A p.D289N (on ENST00000442977 / NM_001198532.1; = p.D288N on NM_018002.3) | Missense Mutation (SNP) | VAF 32/431 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV56328553; called by muse, mutect2
- PCDHA9 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 186/381 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs782552175; called by muse, mutect2, varscan2
- PCDHB4 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 215/318 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.082); catalogued as rs1425672587, COSV52024729; called by muse, varscan2
- PKD1L3 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 43/394 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771683973; called by muse, mutect2, varscan2
- PKP1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 214/455 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs775588543; called by muse, mutect2, varscan2
- PLSCR5 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 147/262 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV101494484; called by muse, mutect2, varscan2
- PLXDC1 | c.906G>A p.P302= | Splice Region (SNP) | VAF 77/181 reads (43%) | catalogued as rs199510802, COSV59551435; called by muse, mutect2, varscan2
- PSTPIP1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 60/524 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs375932577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PUS10 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1423246633, COSV100369404, COSV100369421; called by muse, mutect2
- RALGAPB | c.3802C>G p.P1268A | Missense Mutation (SNP) | VAF 81/575 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99486005; called by muse, mutect2, varscan2
- RHOXF1 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 95/274 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs782248993; called by muse, mutect2, varscan2
- SH2D5 | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 74/364 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs749548969; called by muse, varscan2
- SH3BP5L | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 86/1106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV63538973; called by muse, mutect2
- SLC16A10 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 108/417 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64354500; called by muse, mutect2, varscan2
- SLC52A2 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 85/711 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs532053820; called by muse, mutect2, varscan2
- SMC6 | c.2662C>T p.R888* | Nonsense Mutation (SNP) | VAF 58/235 reads (25%) | catalogued as rs1456122918; called by muse, mutect2, varscan2
- SMTN | c.2476_2478del p.S827del | In Frame Del (DEL) | VAF 66/271 reads (24%) | catalogued as rs749367269; called by pindel, varscan2
- SPTB | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 188/483 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs776814615, COSV67635244; called by muse, mutect2, varscan2
- SUCO | c.3325_3327del p.X1109_splice | Splice Site (DEL) | VAF 51/291 reads (18%) | catalogued as rs760694743; called by pindel, varscan2
- SYTL1 | c.1135G>C p.E379Q (on ENST00000543823; = p.E367Q on NM_032872.3) | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV100539538, COSV100539663; called by muse, mutect2, varscan2
- TMOD3 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 53/342 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100419189, COSV100419199; called by muse, mutect2, varscan2
- TNNI1 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs150769331; called by muse, mutect2, varscan2
- TRIOBP | c.6860G>A p.R2287H (on ENST00000644935 / NM_001039141.3; = p.R574H on NM_007032.5) | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370737996, CM1310692; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRPA1 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs768604987, COSV51556752; called by muse, mutect2, varscan2
- TTN | c.90448G>A p.G30150S (on ENST00000591111; = p.G22726S on NM_003319.4) | Missense Mutation (SNP) | VAF 157/409 reads (38%) | PolyPhen probably damaging (0.999); catalogued as CM1410028; called by muse, mutect2, varscan2
- UBR2 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100867537; called by muse, mutect2
- ZMYM6 | c.3256C>T p.R1086* | Nonsense Mutation (SNP) | VAF 40/210 reads (19%) | catalogued as rs372941645; called by muse, varscan2
- ZNF440 | c.314C>G p.S105* | Nonsense Mutation (SNP) | VAF 110/280 reads (39%) | catalogued as COSV58370819; called by muse, mutect2, varscan2
- ZNF750 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 63/546 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); catalogued as rs377096198; called by muse, mutect2, varscan2
- ZNF85 | c.1271A>C p.K424T | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60215557; called by muse, mutect2, varscan2
- ABCB5 | c.2353G>A p.D785N (on ENST00000404938 / NM_001163941.2; = p.D340N on NM_178559.6) | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABI2 | c.1405G>C p.E469Q (on ENST00000295851 / NM_001375719.1; = p.E431Q on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRA3 | c.1217G>T p.W406L | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRF4 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 207/491 reads (42%) | called by muse, mutect2, varscan2
- ANKRD30B | c.2426G>C p.G809A | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKS1B | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ANKS3 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 91/268 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 39/466 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- ARHGAP31 | c.2960T>G p.L987R | Missense Mutation (SNP) | VAF 44/367 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ASXL3 | c.3997T>G p.L1333V | Missense Mutation (SNP) | VAF 193/346 reads (56%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP11B | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ATP2A1 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- BTNL8 | c.1308T>G p.F436L | Missense Mutation (SNP) | VAF 74/355 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC168 | c.13562T>G p.I4521S | Missense Mutation (SNP) | VAF 72/630 reads (11%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CCNI | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 116/378 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- CD163 | c.2328A>C p.E776D | Missense Mutation (SNP) | VAF 256/377 reads (68%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CDH16 | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 125/484 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CEP170 | c.877A>C p.T293P | Missense Mutation (SNP) | VAF 237/381 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP85L | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 37/469 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.361); called by muse, mutect2
- CFAP100 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- CHST7 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 131/827 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC2A | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 71/246 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CLIC1 | c.131_132insAATGTAC p.T45Mfs*5 | Frame Shift Ins (INS) | VAF 73/455 reads (16%) | called by mutect2, pindel, varscan2
- CNOT6L | c.1051A>C p.K351Q (on ENST00000504123 / NM_001286790.2; = p.K346Q on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL18A1 | c.1393G>T p.D465Y (on ENST00000359759 / NM_130444.3; = p.D230Y on NM_030582.4) | Missense Mutation (SNP) | VAF 71/583 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- COL5A3 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 51/307 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNNA3 | c.1786A>C p.S596R | Missense Mutation (SNP) | VAF 120/219 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DAAM1 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DDX47 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL1 | c.6536C>T p.S2179L | Missense Mutation (SNP) | VAF 146/337 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- DNAH8 | c.4370T>C p.V1457A | Missense Mutation (SNP) | VAF 41/310 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- DOCK3 | c.2869G>A p.D957N | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DYRK1B | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- ECT2 | c.2080C>G p.L694V (on ENST00000392692 / NM_001349098.2; = p.L663V on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/305 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- EFNA1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 177/378 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- EHBP1 | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | called by muse, mutect2, varscan2
- EXOC2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FAM184A | c.1054A>G p.M352V | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAM53C | c.13A>G p.I5V | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FAR2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 53/360 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- FES | c.1754C>G p.T585S | Missense Mutation (SNP) | VAF 61/630 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- FPR2 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 92/2390 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.251); called by muse, mutect2
- GCA | c.397C>G p.Q133E | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GCM1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GJA9 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- GLCE | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GMNC | c.614C>G p.S205* | Nonsense Mutation (SNP) | VAF 45/528 reads (9%) | called by muse, mutect2
- GPR75 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 127/427 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GPR83 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 79/464 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GPRC6A | c.1387C>G p.H463D | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- HLA-E | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- HMCN1 | c.1144C>A p.H382N | Missense Mutation (SNP) | VAF 169/455 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICE1 | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS3 | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 50/589 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- KCNAB1 | c.937G>C p.E313Q (on ENST00000490337 / NM_172160.3; = p.E302Q on NM_003471.3) | Missense Mutation (SNP) | VAF 25/243 reads (10%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- KCTD19 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 75/455 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- KIF21A | c.2638C>T p.Q880* (on ENST00000361418 / NM_001378440.1; = p.Q867* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 218/337 reads (65%) | called by muse, mutect2, varscan2
- KLHL20 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 93/445 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2A | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 141/585 reads (24%) | called by muse, varscan2
- LAMA2 | c.6806C>G p.T2269R | Missense Mutation (SNP) | VAF 50/480 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LARGE1 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 129/382 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- LRRC59 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 48/494 reads (10%) | called by muse, mutect2
- LRRC8B | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 34/270 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAP2 | c.3483T>G p.I1161M | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MORF4L1 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 18/303 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2
- MPDZ | c.5971G>A p.E1991K (on ENST00000319217 / NM_001330637.2; = p.E1962K on NM_003829.5) | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- MTLN | c.416G>C p.*139Sext*66 | Nonstop Mutation (SNP) | VAF 55/161 reads (34%) | called by muse, mutect2, varscan2
- MYBPC2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYT1L | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 114/447 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.164); called by muse, varscan2
- NCOA5 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 125/792 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFASC | c.2755C>T p.P919S (on ENST00000339876 / NM_001378329.1; = p.P1022S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/294 reads (66%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NFATC2 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 25/522 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2
- NMRK1 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NNMT | c.74A>C p.Y25S | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NSRP1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 46/464 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDCD1 | c.1261T>C p.C421R | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OOSP1 | c.364C>G p.H122D | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, varscan2
- OR10R2 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 56/608 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.282); called by muse, mutect2
- OR1R1P | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- OR2S2 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- OTUD3 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 97/432 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PABPC4 | c.1623A>C p.A541= | Splice Region (SNP) | VAF 61/280 reads (22%) | called by muse, mutect2, varscan2
- PARN | c.291C>G p.F97L | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB5 | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 265/547 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- PCDHB6 | c.1660G>A p.D554N | Missense Mutation (SNP) | VAF 96/619 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, varscan2
- PDE7A | c.1001G>T p.R334M (on ENST00000401827 / NM_001242318.3; = p.R308M on NM_002603.4) | Missense Mutation (SNP) | VAF 62/579 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PGLYRP2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 110/315 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.154A>T p.R52* | Nonsense Mutation (SNP) | VAF 30/232 reads (13%) | called by muse, mutect2
- PLXNC1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 85/540 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- POU6F2 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R3A | c.994A>C p.S332R | Missense Mutation (SNP) | VAF 105/179 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RAD51AP2 | c.2707G>C p.E903Q | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RALGAPB | c.1329C>G p.I443M | Missense Mutation (SNP) | VAF 71/716 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- RB1CC1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 112/540 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBL1 | c.1343A>C p.E448A | Missense Mutation (SNP) | VAF 139/460 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- RBM25 | c.2032C>G p.P678A | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- RBM39 | c.1229_1234del p.S410_A411del (on ENST00000253363 / NM_001323424.2; = p.S404_A405del on NM_004902.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 130/483 reads (27%) | called by mutect2, pindel, varscan2
- REST | c.1421C>T p.S474L | Missense Mutation (SNP) | VAF 56/606 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2
- RGS18 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIPK4 | c.2242G>A p.G748R (on ENST00000352483; = p.G700R on NM_020639.3) | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- RPL10L | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 109/382 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCN9A | c.3917G>C p.G1306A (on ENST00000303354; = p.G1295A on NM_002977.3) | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD1A | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 72/733 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by mutect2, varscan2
- SIGLEC6 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 214/2322 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.115); called by muse, mutect2
- SKIL | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 66/480 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- SLC16A3 | c.1010C>G p.A337G | Missense Mutation (SNP) | VAF 29/858 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC23A2 | c.1413G>A p.M471I | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, varscan2
- SLC39A5 | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 86/460 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.066); called by mutect2, varscan2
- SLCO4C1 | c.128A>C p.N43T | Missense Mutation (SNP) | VAF 60/447 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLF1 | c.1697T>C p.I566T | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORBS2 | c.649C>T p.P217S (on ENST00000284776 / NM_021069.5; = p.P263S on NM_003603.6) | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SOX11 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOX9 | c.320_322dup p.R107dup | In Frame Ins (INS) | VAF 79/590 reads (13%) | called by mutect2, pindel, varscan2
- SQLE | c.1445-1G>C p.X482_splice | Splice Site (SNP) | VAF 60/522 reads (11%) | called by muse, mutect2, varscan2
- STARD13 | c.2783G>A p.W928* (on ENST00000336934 / NM_001243476.3; = p.W810* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 91/228 reads (40%) | called by muse, varscan2
- SYNE2 | c.16645G>C p.E5549Q | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TCF7L1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 37/715 reads (5%) | called by muse, mutect2
- TDRD12 | c.2618C>T p.S873F (on ENST00000444215; = p.S878F on NM_001366102.1) | Missense Mutation (SNP) | VAF 169/298 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TRIM52 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- TUBB8B | c.563C>G p.S188* | Nonsense Mutation (SNP) | VAF 44/384 reads (11%) | called by muse, mutect2, varscan2
- UBASH3B | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 116/489 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- UBQLN3 | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 124/383 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP24 | c.6190G>C p.E2064Q | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VPS13B | c.4996C>G p.P1666A | Missense Mutation (SNP) | VAF 82/488 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- VPS37A | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VPS54 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 77/336 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZFC3H1 | c.2529T>G p.D843E | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZIM3 | c.40A>C p.T14P | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ZNF410 | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 132/387 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF415 | c.1559G>C p.G520A | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ZNF471 | c.469A>T p.T157S | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF471 | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 64/317 reads (20%) | called by muse, mutect2, varscan2
- ZNF714 | c.973T>A p.S325T | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ZNF714 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF728 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ZNF91 | c.3463A>T p.I1155F | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.351); called by muse, mutect2
- AASDH | c.609G>A p.G203= | Silent (SNP) | VAF 55/519 reads (11%) | catalogued as rs767249926, COSV52706740; called by muse, mutect2, varscan2
- ABHD2 | c.300C>T p.F100= | Silent (SNP) | VAF 74/703 reads (11%) | called by muse, mutect2, varscan2
- AC008676.3 | c.534C>T p.L178= | Silent (SNP) | VAF 238/508 reads (47%) | catalogued as rs760704939, COSV100400465, COSV56635785; called by muse, mutect2, varscan2
- ADAMTS7 | c.378G>A p.P126= | Silent (SNP) | VAF 198/520 reads (38%) | catalogued as rs370311845; called by muse, varscan2
- ATRNL1 | c.2766C>T p.I922= | Silent (SNP) | VAF 102/322 reads (32%) | catalogued as COSV58093477, COSV58097876; called by muse, mutect2, varscan2
- CACNA1C | c.2997C>G p.V999= | Silent (SNP) | VAF 103/370 reads (28%) | called by muse, mutect2, varscan2
- CACNA1E | c.586C>A p.R196= | Silent (SNP) | VAF 236/416 reads (57%) | catalogued as COSV100701362, COSV100701897; called by muse, mutect2, varscan2
- CD33 | c.933G>A p.Q311= | Silent (SNP) | VAF 84/578 reads (15%) | called by muse, mutect2, varscan2
- CEP350 | c.3495G>A p.S1165= | Silent (SNP) | VAF 290/529 reads (55%) | catalogued as rs535788115, COSV62605271; called by muse, varscan2
- CNTNAP4 | c.1368C>T p.V456= | Silent (SNP) | VAF 158/247 reads (64%) | catalogued as rs142575528, COSV56681015; called by muse, mutect2, varscan2
- CPNE3 | c.327G>A p.K109= | Silent (SNP) | VAF 36/543 reads (7%) | called by muse, mutect2
- CWC22 | c.2601T>C p.D867= | Silent (SNP) | VAF 102/350 reads (29%) | called by muse, mutect2, varscan2
- CYP1A1 | c.672C>T p.F224= | Silent (SNP) | VAF 295/485 reads (61%) | catalogued as rs144413202; called by muse, mutect2, varscan2
- DAGLB | c.1125G>T p.G375= | Silent (SNP) | VAF 35/476 reads (7%) | catalogued as rs749340631; called by muse, mutect2
- DNAH17 | c.90G>A p.L30= | Silent (SNP) | VAF 70/481 reads (15%) | called by muse, mutect2, varscan2
- DPH6 | c.276G>A p.E92= | Silent (SNP) | VAF 45/272 reads (17%) | called by muse, mutect2, varscan2
- DUSP8 | c.1086C>T p.P362= | Silent (SNP) | VAF 175/512 reads (34%) | catalogued as rs771396419; called by muse, mutect2, varscan2
- DUSP9 | c.369C>G p.L123= | Silent (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- F2 | c.279G>A p.A93= | Silent (SNP) | VAF 55/452 reads (12%) | catalogued as rs778280660, COSV61316709; called by muse, mutect2, varscan2
- F5 | c.1269C>T p.I423= | Silent (SNP) | VAF 50/532 reads (9%) | called by muse, mutect2
- FERMT1 | c.1479G>A p.L493= | Silent (SNP) | VAF 62/776 reads (8%) | catalogued as COSV54090579; called by muse, mutect2
- FGD5 | c.3357G>A p.T1119= | Silent (SNP) | VAF 221/306 reads (72%) | catalogued as rs1401502930; called by muse, mutect2, varscan2
- FTMT | c.510G>T p.V170= | Silent (SNP) | VAF 67/384 reads (17%) | catalogued as COSV58419855, COSV58421630; called by muse, mutect2, varscan2
- GABRA5 | c.936C>T p.P312= | Silent (SNP) | VAF 62/438 reads (14%) | called by muse, mutect2, varscan2
- GFRAL | c.558G>A p.L186= | Silent (SNP) | VAF 48/455 reads (11%) | called by muse, mutect2, varscan2
- GUCA1A | c.39G>C p.L13= | Silent (SNP) | VAF 69/568 reads (12%) | catalogued as COSV50004873; called by muse, mutect2, varscan2
- HCN1 | c.45C>T p.D15= | Silent (SNP) | VAF 75/272 reads (28%) | catalogued as rs760319799, COSV100298074; called by muse, varscan2
- HPD | c.261G>A p.V87= | Silent (SNP) | VAF 51/284 reads (18%) | catalogued as COSV56641826; called by muse, mutect2, varscan2
- HPS1 | c.30C>T p.G10= | Silent (SNP) | VAF 116/310 reads (37%) | catalogued as rs550478432, COSV100282740; called by muse, mutect2, varscan2
- IGHE | c.1161C>T p.F387= | Silent (SNP) | VAF 49/392 reads (13%) | catalogued as rs1555456594; called by muse, mutect2, varscan2
- IPO7 | c.2751G>A p.E917= | Silent (SNP) | VAF 47/308 reads (15%) | called by muse, mutect2, varscan2
- KEL | c.174C>G p.L58= | Silent (SNP) | VAF 127/435 reads (29%) | catalogued as COSV62333969; called by muse, mutect2, varscan2
- LEPROT | c.36C>T p.F12= | Silent (SNP) | VAF 87/372 reads (23%) | called by muse, mutect2, varscan2
- LHCGR | c.1077T>C p.Y359= | Silent (SNP) | VAF 113/332 reads (34%) | called by muse, mutect2, varscan2
- LRFN5 | c.2103T>C p.A701= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as COSV99984493; called by muse, mutect2, varscan2
- MAGEC3 | c.723G>T p.L241= | Silent (SNP) | VAF 69/251 reads (27%) | catalogued as COSV53580599; called by muse, mutect2, varscan2
- MKX | c.921G>A p.E307= | Silent (SNP) | VAF 59/624 reads (9%) | called by muse, mutect2
- MPDZ | c.6126G>C p.G2042= (on ENST00000319217 / NM_001330637.2; = p.G2013= on NM_003829.5) | Silent (SNP) | VAF 61/251 reads (24%) | called by muse, mutect2, varscan2
- NCAN | c.3066A>G p.T1022= | Silent (SNP) | VAF 51/268 reads (19%) | catalogued as rs1245031905; called by muse, mutect2, varscan2
- NOVA1 | c.1329A>C p.T443= | Silent (SNP) | VAF 135/352 reads (38%) | catalogued as COSV57471613; called by muse, mutect2, varscan2
- OR10J3 | c.138C>T p.I46= | Silent (SNP) | VAF 112/556 reads (20%) | catalogued as COSV59953920, COSV59955339; called by muse, mutect2, varscan2
- OR3A1 | c.357C>T p.T119= | Silent (SNP) | VAF 256/406 reads (63%) | catalogued as rs144174017; called by muse, varscan2
- OR4C46 | c.117A>C p.G39= | Silent (SNP) | VAF 52/366 reads (14%) | catalogued as rs527653530, COSV60219545; called by muse, mutect2, varscan2
- OSBPL10 | c.288C>T p.F96= | Silent (SNP) | VAF 55/241 reads (23%) | catalogued as rs549731324, COSV67343817; called by muse, mutect2, varscan2
- PCYOX1 | c.255C>T p.Y85= | Silent (SNP) | VAF 187/423 reads (44%) | catalogued as rs775352401; called by muse, mutect2, varscan2
- PHC1 | c.2562C>G p.R854= | Silent (SNP) | VAF 72/307 reads (23%) | called by muse, mutect2, varscan2
- PHF2 | c.270C>T p.I90= | Silent (SNP) | VAF 41/337 reads (12%) | catalogued as rs368398809, COSV63680419; called by muse, mutect2, varscan2
- PIWIL1 | c.174A>G p.G58= | Silent (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- PLEC | c.9279C>T p.I3093= (on ENST00000322810 / NM_201380.4; = p.I2983= on NM_000445.5) | Silent (SNP) | VAF 58/849 reads (7%) | called by muse, mutect2
- PPP1R9B | c.2133G>A p.Q711= | Silent (SNP) | VAF 60/379 reads (16%) | called by muse, mutect2, varscan2
- PTGES3 | c.231A>G p.L77= | Silent (SNP) | VAF 32/284 reads (11%) | called by muse, mutect2, varscan2
- RNF181 | c.357G>A p.E119= | Silent (SNP) | VAF 27/844 reads (3%) | called by muse, mutect2
- RYR3 | c.348C>T p.S116= | Silent (SNP) | VAF 88/310 reads (28%) | catalogued as rs374563732, COSV101213540; ClinVar: likely benign; called by muse, varscan2
- SLC2A3 | c.57C>T p.I19= | Silent (SNP) | VAF 50/352 reads (14%) | catalogued as rs745373148; called by muse, mutect2, varscan2
- SLC50A1 | c.126C>G p.V42= | Silent (SNP) | VAF 45/441 reads (10%) | catalogued as COSV57597061; called by muse, mutect2, varscan2
- SPG7 | c.1893G>T p.L631= (on ENST00000268704; = p.L638= on NM_003119.4) | Silent (SNP) | VAF 128/252 reads (51%) | called by muse, mutect2, varscan2
- SSTR4 | c.849C>G p.L283= | Silent (SNP) | VAF 62/594 reads (10%) | catalogued as COSV99658811; called by muse, mutect2, varscan2
- SSTR4 | c.918C>T p.A306= | Silent (SNP) | VAF 51/762 reads (7%) | called by muse, mutect2
- TBCB | c.57C>G p.L19= | Silent (SNP) | VAF 32/242 reads (13%) | called by muse, mutect2, varscan2
- TENT5C | c.828C>A p.I276= | Silent (SNP) | VAF 66/482 reads (14%) | called by muse, mutect2, varscan2
- TNN | c.201C>T p.D67= | Silent (SNP) | VAF 106/588 reads (18%) | catalogued as rs779026691, COSV53432709; called by muse, mutect2, varscan2
- TTC23 | c.1083C>T p.L361= | Silent (SNP) | VAF 151/683 reads (22%) | catalogued as rs1340653254, COSV100018338; called by muse, mutect2, varscan2
- TTC6 | c.510G>A p.S170= | Silent (SNP) | VAF 38/365 reads (10%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.25C>T p.L9= | Silent (SNP) | VAF 64/438 reads (15%) | catalogued as COSV53021624; called by muse, mutect2, varscan2
- UTS2R | c.789C>T p.I263= | Silent (SNP) | VAF 97/682 reads (14%) | catalogued as rs746346530; called by muse, mutect2, varscan2
- UXS1 | c.27C>T p.L9= | Silent (SNP) | VAF 67/220 reads (30%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.816C>G p.L272= | Silent (SNP) | VAF 86/327 reads (26%) | catalogued as COSV52066008, COSV52070000, COSV99363788; called by muse, mutect2, varscan2
- ZNF131 | c.1728G>A p.E576= (on ENST00000509156 / NM_001330707.2; = p.E542= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 96/506 reads (19%) | called by muse, mutect2, varscan2
- BIN3 | c.339-1049G>A | Intron (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- C6orf136 | c.72+462G>C | Intron (SNP) | VAF 102/779 reads (13%) | catalogued as COSV53314324; called by muse, mutect2, varscan2
- CBFA2T2 | c.719+574C>G | Intron (SNP) | VAF 108/657 reads (16%) | called by muse, varscan2
- CRCP | c.-67G>A | 5'UTR (SNP) | VAF 94/1052 reads (9%) | called by muse, mutect2
- DDX10 | c.2450+14A>G | Intron (SNP) | VAF 36/306 reads (12%) | catalogued as rs1156588604; called by muse, varscan2
- IGFN1 | c.1241+2877T>C | Intron (SNP) | VAF 93/576 reads (16%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+9187A>G | Intron (SNP) | VAF 106/353 reads (30%) | called by muse, mutect2, varscan2
- NPAP1L | n.256G>T | RNA (SNP) | VAF 62/235 reads (26%) | catalogued as rs1312108962; called by muse, mutect2, varscan2
- OR2T2 | chr1:248441595 A>G | 5'Flank (SNP) | VAF 48/864 reads (6%) | catalogued as rs1240049350; called by muse, mutect2
- SAMD8 | c.-37G>T | 5'UTR (SNP) | VAF 67/413 reads (16%) | catalogued as rs910375826; called by muse, mutect2, varscan2
- SLC9A3 | c.*414G>C | 3'UTR (SNP) | VAF 27/134 reads (20%) | called by muse, mutect2, varscan2
- WFIKKN1 | c.-1C>T | 5'UTR (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26671736 C>T | 5'Flank (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2, varscan2
- ZNF286B | n.1029C>T | RNA (SNP) | VAF 261/413 reads (63%) | called by muse, mutect2, varscan2
